Somatic mutation profile of tumor specimen TARGET-10-PAPHYM-09A (aliquot TARGET-10-PAPHYM-09A-01D) from TARGET case TARGET-10-PAPHYM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.1 years (3,309 days).
Specimen TARGET-10-PAPHYM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 725068d1-c899-4391-b060-fc9f55a2a220.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPHYM-10A (Blood Derived Normal), aliquot TARGET-10-PAPHYM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/002278c2-89ad-4ae7-a91c-9a7e9e060e5b

The open-access MAF lists 26 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 4, Frame Shift Ins 2, In Frame Del 1, Intron 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF11 | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs969648888; called by muse, mutect2, varscan2
- CHD4 | c.2419G>A p.E807K (on ENST00000357008 / NM_001363606.2; = p.E820K on NM_001273.5) | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58913075; called by muse, mutect2, varscan2
- DNAH10 | c.13406C>T p.P4469L (on ENST00000409039; = p.P4408L on NM_207437.3) | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs529268286; called by muse, mutect2, varscan2
- DOCK3 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as rs587776362, COSV56514458; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERG | c.1109A>G p.D370G (on ENST00000398919 / NM_001243428.1; = p.D346G on NM_004449.4) | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55729043; called by muse, mutect2
- FLT3 | c.1774G>T p.V592F | Missense Mutation (SNP) | VAF 47/82 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV54050958; called by muse, mutect2, varscan2
- MAGEB10 | c.235C>A p.H79N | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as COSV100775098; called by muse, mutect2
- PTPRN2 | c.2461G>A p.G821R | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67061168; called by muse, mutect2, varscan2
- WWC3 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.429); catalogued as rs939193849, COSV66504286; called by muse, mutect2, varscan2
- ABCA5 | c.718A>C p.I240L | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.592); called by muse, varscan2
- ADAM10 | c.828A>G p.R276= | Splice Region (SNP) | VAF 59/185 reads (32%) | called by muse, mutect2, varscan2
- FAM172A | c.1141_1143del p.S381del | In Frame Del (DEL) | VAF 10/68 reads (15%) | called by pindel, varscan2
- FPGT | c.1610C>A p.T537N | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2
- HELZ | c.1873_1874insAGACCCCCCTGAA p.T625Kfs*11 | Frame Shift Ins (INS) | VAF 13/99 reads (13%) | called by mutect2, pindel
- KCNK2 | c.597A>G p.I199M (on ENST00000444842 / NM_001017425.3; = p.I184M on NM_014217.4) | Missense Mutation (SNP) | VAF 69/214 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- MANBA | c.2020dup p.Q674Pfs*8 (on ENST00000642252; = p.Q628Pfs*8 on NM_005908.4) | Frame Shift Ins (INS) | VAF 83/415 reads (20%) | called by mutect2, pindel, varscan2
- PAK1 | c.999-1G>T p.X333_splice | Splice Site (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- PKHD1 | c.7094C>T p.A2365V | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TRIOBP | c.5753C>A p.A1918E (on ENST00000644935 / NM_001039141.3; = p.A205E on NM_007032.5) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2
- WTIP | c.1271C>A p.T424N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.01); called by mutect2, varscan2
- ZFP36L2 | c.17T>G p.L6R | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MAGEB1 | c.822G>A p.P274= | Silent (SNP) | VAF 39/164 reads (24%) | catalogued as rs772666054, COSV100974859; called by muse, mutect2, varscan2
- OR2A14 | c.825G>A p.L275= | Silent (SNP) | VAF 15/206 reads (7%) | called by muse, mutect2
- SIX5 | c.2178C>T p.T726= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs1302220666; called by muse, mutect2, varscan2
- USP45 | c.1776G>T p.G592= | Silent (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2
- KCNU1 | c.2737-1913T>C | Intron (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
